Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2MY, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2MY-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. RIGHT UPPER PARATHYROID (EXCISION): PARATHYROID AND FIBROADIPOSE TISSUE (500MG). PARATHYROID ACCOUNTS FOR 40% OF THE SPECIMEN.
2. RIGHT LOWER PARATHYROID (EXCISION): PARATHYROID TISSUE WITH ADJACENT FIBROADIPOSE AND BENIGN THYROID TISSUE (450MG). PARATHYROID ACCOUNTS FOR 25% OF THE SPECIMEN.
3. BIOPSY LEFT LOWER PARATHYROID GLAND (BIOPSY): PARATHYROID TISSUE (6MG).

NOTE: Tissue block exhausted on frozen section. No frozen section control present.

4. THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy.

TUMOR SITE:

Right superior lobe and isthmus.

ICD-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
fw 8/18/11

HISTOLOGIC TYPE:

Papillary carcinoma.

TUMOR SIZE:

Greatest dimension: 1.3cm.

FOCALITY:

Unifocal.

LYMPH NODES:

None submitted.

EXTENT OF INVASION

PRIMARY TUMOR:

pT1b: Tumor >1cm but <2cm, limited to thyroid.

REGIONAL LYMPH NODES:

pNx: Cannot be assessed.

DISTANT METASTASIS:

pMx: Cannot be assessed.

[page 2 of 2]
pMx: Cannot be assessed.

MARGINS:

Margins are uninvolved.

Distance of invasive carcinoma from nearest margin: <1mm.

Specify margin: Anterior and Posterior.

VENOUS/LYMPHATIC INVASION:

Present.

ADDITIONAL PATHOLOGIC FINDINGS:

Other: Multinodular hyperplasia.

Source: NCI Genomic Data Commons file 9f43340f-465d-4a24-88ac-545eeeff7e07 (TCGA-ET-A2MY.E90820AD-FDE0-40AD-B8C3-F5452941AFBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).